Somatic mutation profile of tumor specimen C3L-03984-01 (aliquot CPT0242670007) from CPTAC case C3L-03984, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 59.8 years (21,834 days).
Specimen C3L-03984-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1131c268-dea7-4418-836c-fe7c46152524.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03984-31 (Blood Derived Normal), aliquot CPT0242830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee863053-cfa2-46dd-9bc1-7817b4e9735b

The open-access MAF lists 506 somatic variants for this specimen: 352 protein-altering or splice-affecting, 107 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 294, Silent 107, Intron 24, Nonsense Mutation 22, Splice Site 17, RNA 11, Frame Shift Del 10, Splice Region 6, 5'UTR 5, Frame Shift Ins 3, 3'UTR 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 274/486 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NEXMIF | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 6/134 reads (4%) | catalogued as rs1556016731, CM156012, COSV50023631; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 59/233 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs368828473, COSV52208810; called by muse, mutect2, varscan2
- AC004832.3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56741583; called by muse, mutect2, varscan2
- AC097636.1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs749884592; called by muse, mutect2
- ADAMTS5 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV104373662, COSV53185423; called by muse, mutect2
- ADARB2 | c.1241A>C p.K414T | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101187334; called by muse, mutect2
- AGBL1 | c.466C>G p.R156G | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs201712819; called by muse, mutect2
- BRINP3 | c.2149G>T p.G717C | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100819196, COSV66543104; called by muse, mutect2, varscan2
- CARMIL2 | c.3259G>A p.A1087T | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs375479502, COSV54667427; called by muse, mutect2
- CCBE1 | c.774C>T p.P258= | Splice Region (SNP) | VAF 31/289 reads (11%) | catalogued as COSV67950344; called by muse, mutect2, varscan2
- CCDC88A | c.255G>C p.Q85H | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV55055678; called by muse, mutect2
- CCSER1 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 66/320 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.116); catalogued as rs372893740, COSV100392587; called by muse, mutect2, varscan2
- CD28 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.116); catalogued as rs1202305808, COSV100142647, COSV99048002; called by muse, mutect2, varscan2
- CDC27 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs766725312; called by muse, mutect2
- CHL1 | c.3367C>A p.P1123T (on ENST00000397491 / NM_001253387.1; = p.P1139T on NM_006614.4) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.356); catalogued as rs746970271, COSV56588856; called by muse, mutect2, varscan2
- CHST8 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 20/363 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749617284; called by muse, mutect2
- CMYA5 | c.9748G>A p.D3250N | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as rs1024607100; called by muse, mutect2, varscan2
- COL11A1 | c.2018G>T p.G673V | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765120248; called by muse, mutect2
- COL12A1 | c.8740C>A p.Q2914K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV59412375; called by muse, mutect2, varscan2
- COL19A1 | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV59577893; called by muse, mutect2, varscan2
- COL3A1 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100482737; called by muse, mutect2, varscan2
- CPQ | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.029); catalogued as rs183172032, COSV55152812; called by muse, varscan2
- CPS1 | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 15/170 reads (9%) | catalogued as rs1337182136; called by muse, mutect2
- CPXM2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs145723018; called by muse, mutect2
- CRB2 | c.1720G>C p.A574P | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.335); catalogued as COSV63501723; called by muse, mutect2, varscan2
- CREBBP | c.5302C>T p.R1768C | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99268435; called by muse, mutect2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 48/203 reads (24%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CUBN | c.7534-3C>A | Splice Region (SNP) | VAF 30/324 reads (9%) | catalogued as COSV64723637; called by muse, mutect2
- CYLC2 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV66338495; called by muse, mutect2
- DNAH11 | c.6245G>A p.R2082Q | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs563280837, COSV60956774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFCAB5 | c.597G>C p.L199F | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV57925348; called by muse, mutect2
- ELF3 | c.1073C>G p.S358* | Nonsense Mutation (SNP) | VAF 46/366 reads (13%) | catalogued as COSV100668618, COSV62839941; called by muse, mutect2, varscan2
- ERICH3 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 14/296 reads (5%) | catalogued as COSV58609878, COSV58615836; called by muse, mutect2
- EXOC2 | c.1837G>T p.G613* | Nonsense Mutation (SNP) | VAF 7/100 reads (7%) | catalogued as rs1017759778; called by muse, mutect2
- FAM117B | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as rs752621082; called by muse, mutect2
- FIBP | c.928-5C>T | Splice Region (SNP) | VAF 32/261 reads (12%) | catalogued as rs548208317; called by muse, mutect2, varscan2
- FMN2 | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV60459346; called by muse, mutect2
- FOXF2 | c.199A>T p.S67C | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); catalogued as rs773094257; called by muse, mutect2, varscan2
- FOXI1 | c.1095C>A p.N365K | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV100089042; called by muse, mutect2, varscan2
- GABRA4 | c.1312C>A p.R438S | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs201220260; called by muse, mutect2, varscan2
- GOLGA2 | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs751797429; called by muse, mutect2, varscan2
- GPR25 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV58497618; called by muse, mutect2, varscan2
- GRTP1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs771947417, COSV100964923; called by muse, mutect2, varscan2
- GSTK1 | c.383G>T p.R128M | Missense Mutation (SNP) | VAF 30/480 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as COSV64424784; called by muse, mutect2
- HCN4 | c.1132del p.R378Afs*30 | Frame Shift Del (DEL) | VAF 22/245 reads (9%) | catalogued as COSV56084416, COSV99984381; called by mutect2, pindel
- HGF | c.226A>T p.R76W | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55946108; called by muse, mutect2
- HNRNPDL | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.559); catalogued as rs752710041, COSV55022200, COSV99787105; called by muse, mutect2
- ITGA7 | c.3517G>A p.D1173N (on ENST00000555728; = p.D1129N on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.336); catalogued as rs572158420, COSV57701160; called by muse, mutect2
- KCNJ1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 102/436 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.45); catalogued as COSV100131550; called by muse, mutect2, varscan2
- KIF2B | c.520C>G p.R174G | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs769176818, COSV52126857; called by muse, mutect2, varscan2
- MAP3K10 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV53425680; called by muse, mutect2
- MCMDC2 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100552264, COSV58040794; called by muse, mutect2, varscan2
- MED13 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs878872363; called by muse, mutect2, varscan2
- MEST | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.802); catalogued as rs1160048889; called by muse, mutect2
- MKLN1 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100759740; called by muse, mutect2, varscan2
- MMP28 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 23/267 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs372991755; called by muse, mutect2
- MMRN1 | c.1388T>C p.I463T | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs1228178026; called by muse, mutect2, varscan2
- MON1B | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV50246049; called by muse, mutect2, varscan2
- MOV10L1 | c.2421C>A p.D807E | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148358948; called by muse, mutect2, varscan2
- MYH4 | c.4147G>A p.A1383T | Missense Mutation (SNP) | VAF 41/369 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as rs1256887047, COSV55118883; called by muse, mutect2, varscan2
- MYL1 | c.317A>T p.K106M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58976862; called by muse, mutect2, varscan2
- NCOA4 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs782118571; called by muse, mutect2
- NLRP7 | c.1277A>T p.Q426L | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs778344752; called by muse, mutect2, varscan2
- NPSR1 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 11/146 reads (8%) | catalogued as COSV63102897; called by muse, mutect2
- NTM | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 40/361 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66196004; called by muse, mutect2, varscan2
- OR8K3 | c.797C>A p.S266Y | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV57130668, COSV57131689; called by muse, mutect2, varscan2
- OTOGL | c.2402G>A p.R801H (on ENST00000547103; = p.R792H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs771349732, COSV72006817; called by muse, mutect2, varscan2
- PAX1 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767792155, COSV68273467; called by muse, mutect2, varscan2
- PCDH15 | c.3101G>T p.R1034L | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as rs907693214, CM163812, COSV57270708; called by muse, mutect2, varscan2
- PCDHA3 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 34/339 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65364216; called by muse, mutect2
- PCDHB6 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50730486; called by muse, mutect2
- PCDHGA1 | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 98/487 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as COSV65295280; called by muse, mutect2, varscan2
- PCDHGB1 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 24/288 reads (8%) | catalogued as rs751150104, COSV99535197, COSV99537985; called by muse, mutect2
- PDE3A | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV62984569; called by muse, mutect2, varscan2
- PEAK3 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV59232995; called by muse, mutect2
- PLA2G6 | c.1957G>A p.G653S | Missense Mutation (SNP) | VAF 25/387 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754204295, CM130769, COSV100140485; called by muse, mutect2
- PLXDC2 | c.324+1G>C p.X108_splice | Splice Site (SNP) | VAF 7/145 reads (5%) | catalogued as COSV101025362; called by muse, mutect2
- PLXDC2 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774243560; called by muse, mutect2, varscan2
- PRAMEF6 | c.377T>G p.L126R | Missense Mutation (SNP) | VAF 68/387 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.125); catalogued as COSV61910049; called by muse, mutect2, varscan2
- PRDM9 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 44/536 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.775); catalogued as rs191143245; called by muse, mutect2
- PRDM9 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.084); catalogued as rs1418217538, COSV57012453; called by muse, mutect2, varscan2
- PRKN | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 56/489 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV58227192; called by muse, mutect2, varscan2
- PRKN | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 60/624 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.868); catalogued as rs748892763, COSV58262516; called by muse, mutect2
- PSMA8 | c.102G>A p.A34= | Splice Region (SNP) | VAF 12/113 reads (11%) | catalogued as COSV100379201, COSV57601028; called by muse, mutect2
- PTPRN2 | c.1717G>T p.A573S | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.739); catalogued as COSV104431103; called by muse, mutect2
- R3HDML | c.86C>A p.A29D | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV53836457; called by muse, mutect2
- RHOB | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs963666458; called by muse, mutect2
- RP1L1 | c.5501G>T p.G1834V | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.433); catalogued as COSV66760104; called by muse, mutect2, varscan2
- RPL4 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 46/409 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as rs573314657; called by muse, mutect2, varscan2
- RYR2 | c.12232C>A p.L4078I | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs747750895; called by muse, mutect2
- SCAF11 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 28/103 reads (27%) | catalogued as COSV101014608; called by muse, mutect2, varscan2
- SIPA1L3 | c.3646G>T p.E1216* | Nonsense Mutation (SNP) | VAF 23/155 reads (15%) | catalogued as COSV55922241; called by muse, mutect2, varscan2
- SLIT3 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762538569; called by muse, mutect2, varscan2
- SNAP25 | c.51G>T p.R17S | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV54774661; called by muse, mutect2, varscan2
- SNCAIP | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 27/430 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs773517325, COSV54402471; called by muse, mutect2
- SNTG1 | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 30/246 reads (12%) | catalogued as COSV52433296; called by muse, mutect2, varscan2
- SP140L | c.1281G>T p.E427D | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54741571; called by muse, mutect2
- SPARCL1 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.157); catalogued as rs1465110564, COSV56806530; called by muse, mutect2
- STRA6 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs371354066; called by muse, mutect2, varscan2
- SVOPL | c.392C>A p.T131N | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1374042814; called by muse, mutect2, varscan2
- SYT9 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 29/417 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs567812209, COSV59626171; called by muse, mutect2
- TAAR5 | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV57798904; called by muse, mutect2, varscan2
- TACR3 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as COSV59209059, COSV99079947; called by muse, mutect2, varscan2
- TAT | c.35del p.G12Afs*23 | Frame Shift Del (DEL) | VAF 110/504 reads (22%) | catalogued as COSV100587653; called by mutect2, pindel, varscan2
- TBC1D21 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV55995523; called by muse, varscan2
- TEKT1 | c.718del p.A240Pfs*29 | Frame Shift Del (DEL) | VAF 44/220 reads (20%) | catalogued as COSV100106253; called by mutect2, pindel*, varscan2
- TINAG | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.514); catalogued as rs1453448149, COSV52516095; called by muse, mutect2, varscan2
- TMEM232 | c.1672G>T p.V558L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1361260938; called by muse, mutect2, varscan2
- TRIML1 | c.759G>T p.R253S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60194332, COSV60196016; called by muse, mutect2, varscan2
- TSHR | c.2212G>A p.V738I | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.023); catalogued as COSV53318382; called by muse, mutect2, varscan2
- TTN | c.55297+2T>C p.X18433_splice (on ENST00000591111; = p.X11009_splice on NM_003319.4) | Splice Site (SNP) | VAF 25/228 reads (11%) | catalogued as COSV60151508; called by muse, mutect2, varscan2
- UBN1 | c.3215C>T p.A1072V | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs772292948, COSV99278896; called by muse, mutect2, varscan2
- USH2A | c.15584C>A p.T5195N | Missense Mutation (SNP) | VAF 32/462 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs915038916, COSV99379614; called by muse, mutect2
- VEGFA | c.617G>T p.C206F (on ENST00000523873 / NM_001171623.1; = p.C369F on NM_003376.6) | Missense Mutation (SNP) | VAF 84/567 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57878139; called by muse, varscan2
- WDR17 | c.3371G>T p.S1124I | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54573761; called by muse, mutect2, varscan2
- WNT10B | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 46/775 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs767121886; called by muse, mutect2
- XCL2 | c.62-1G>T p.X21_splice | Splice Site (SNP) | VAF 24/116 reads (21%) | catalogued as COSV99057443; called by muse, mutect2, varscan2
- ZNF418 | c.47A>G p.Q16R | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV68676172; called by muse, mutect2
- ZNF43 | c.2409A>T p.Q803H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61683331; called by muse, mutect2, varscan2
- ZNF586 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 63/498 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as rs770528695, COSV101197750, COSV66972525; called by muse, mutect2, varscan2
- ZNF804B | c.1670G>A p.S557N | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60862954; called by muse, mutect2, varscan2
- ZNF836 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.918); catalogued as rs1174868003; called by muse, mutect2, varscan2
- ZSWIM5 | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1398475254, COSV62735289; called by muse, mutect2, varscan2
- ZYX | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 35/350 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.96); catalogued as rs750508246; called by muse, mutect2, varscan2
- ABCA4 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 31/459 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- ACAA1 | c.442T>G p.C148G | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAD1 | c.414G>T p.Q138H | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ADCK2 | c.60G>C p.E20D | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ADCY2 | c.2596G>T p.E866* | Nonsense Mutation (SNP) | VAF 19/190 reads (10%) | called by muse, mutect2, varscan2
- ADGB | c.4892A>T p.E1631V | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADGRB3 | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.007); called by muse, mutect2
- ADGRD1 | c.509T>A p.V170D | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- ADGRL2 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- AKAP12 | c.2668C>G p.H890D | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- AKR7L | c.839A>G p.H280R | Missense Mutation (SNP) | VAF 29/500 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- ANK3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 17/370 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); called by muse, mutect2
- ANO4 | c.2751G>T p.M917I (on ENST00000392977 / NM_001286615.2; = p.M882I on NM_178826.4) | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- ANTXRL | c.1410+1G>T p.X470_splice | Splice Site (SNP) | VAF 16/534 reads (3%) | called by muse, mutect2
- ARHGEF10 | c.212C>G p.P71R (on ENST00000398564; = p.P47R on NM_014629.4) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ARIH2 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2
- ASB9 | c.875T>G p.L292R | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATM | c.2620G>C p.E874Q | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ATM | c.3305del p.G1102Efs*7 | Frame Shift Del (DEL) | VAF 59/266 reads (22%) | called by mutect2, pindel, varscan2
- ATP2B1 | c.2614A>G p.T872A | Missense Mutation (SNP) | VAF 87/302 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BMX | c.510+1G>A p.X170_splice | Splice Site (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2
- C20orf96 | c.504G>T p.R168S (on ENST00000360321 / NM_153269.3; = p.R167S on NM_080571.1) | Missense Mutation (SNP) | VAF 47/566 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.229); called by muse, mutect2
- CAD | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- CALB2 | c.730A>T p.R244* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- CAPN15 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC158 | c.787C>A p.Q263K | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); called by muse, mutect2
- CCDC30 | c.687G>T p.Q229H (on ENST00000340612; = p.Q186H on NM_001080850.3) | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CCDC83 | c.151A>T p.R51W | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCN3 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CDH12 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.7); called by muse, mutect2
- CFAP251 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); called by muse, mutect2
- CHST2 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CLPX | c.893-1G>T p.X298_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- CMPK2 | c.1144A>G p.R382G | Missense Mutation (SNP) | VAF 52/484 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTN4 | c.577A>T p.T193S | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CNTNAP4 | c.1462G>T p.G488C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CPXM2 | c.1780C>A p.L594M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2
- CRACR2A | c.1755G>T p.K585N | Missense Mutation (SNP) | VAF 188/496 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK2A3 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 56/473 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CTBS | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- DACT3 | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 62/408 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DDX39B | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DGKI | c.2635G>T p.G879W | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2
- DKK2 | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DLK1 | c.132-1G>T p.X44_splice | Splice Site (SNP) | VAF 16/161 reads (10%) | called by muse, mutect2
- DMBT1 | c.3278C>G p.S1093* (on ENST00000338354 / NM_001377530.1; = p.S594* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
- DNAAF1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 10/261 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- DNAH6 | c.7611G>T p.E2537D | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.251); called by muse, mutect2
- DNAJB6 | c.950A>T p.K317M | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DRC1 | c.620T>A p.M207K | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- DUSP29 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 50/516 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EARS2 | c.614G>T p.W205L | Missense Mutation (SNP) | VAF 27/572 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- EEF1B2 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- EOMES | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 78/320 reads (24%) | called by muse, mutect2, varscan2
- EXOC2 | c.2551G>T p.A851S | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM104B | c.86G>T p.R29I | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FAM25A | c.203C>G p.T68R | Missense Mutation (SNP) | VAF 70/510 reads (14%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM83B | c.2878C>A p.R960S | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- FBXO32 | c.944A>G p.Q315R | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.358); called by muse, mutect2
- FBXO40 | c.1955G>C p.W652S | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO43 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FGD5 | c.1600A>G p.S534G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF12 | c.728C>T p.T243I (on ENST00000454309 / NM_021032.5; = p.T181I on NM_004113.6) | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); called by muse, mutect2
- FPGS | c.1195_1196delinsT p.R399Sfs*27 | Frame Shift Del (DEL) | VAF 12/146 reads (8%) | called by pindel, varscan2*
- GABRA1 | c.301A>T p.R101W | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA4 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 28/257 reads (11%) | called by muse, mutect2, varscan2
- GABRB1 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GABRG2 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- GATA4 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- GFPT1 | c.2024C>A p.A675D (on ENST00000357308 / NM_001244710.2; = p.A657D on NM_002056.4) | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2
- GIGYF2 | c.3172del p.A1058Hfs*4 | Frame Shift Del (DEL) | VAF 18/166 reads (11%) | called by mutect2, varscan2
- GOLGA6L2 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 24/449 reads (5%) | called by muse, mutect2
- GPR171 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- GSDMC | c.1448C>T p.T483I | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF3C1 | c.3310G>T p.V1104L | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- GZMM | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- HIPK2 | c.2498G>T p.R833L | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IER3 | c.210+2dup | Splice Region (INS) | VAF 133/629 reads (21%) | called by mutect2, pindel, varscan2
- IFNGR2 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 335/767 reads (44%) | called by muse, mutect2, varscan2
- IGHD | c.763A>T p.S255C | Missense Mutation (SNP) | VAF 53/512 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- IGSF1 | c.2428C>G p.L810V | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- INSM1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGA4 | c.1751G>C p.G584A | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- JAKMIP3 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 27/308 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCNA2 | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNH5 | c.1075G>C p.V359L | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.088); called by muse, mutect2
- KCNMA1 | c.983G>T p.W328L | Missense Mutation (SNP) | VAF 53/321 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- KCNT2 | c.2218A>T p.R740W | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM5A | c.3184C>T p.L1062F | Missense Mutation (SNP) | VAF 21/615 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KEL | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 48/496 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- KIAA0408 | c.1409A>T p.E470V | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- KIAA1109 | c.1292A>T p.Y431F | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.07); called by muse, mutect2
- KIAA1614 | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- KIF27 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 27/313 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2
- KIF4B | c.2490G>T p.R830S | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- KLHL1 | c.438A>T p.Q146H | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); called by muse, mutect2
- KMT2A | c.8567A>G p.N2856S | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KRTAP10-12 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 54/347 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LARP1B | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 56/392 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LGR5 | c.717-1G>C p.X239_splice | Splice Site (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- LRRC70 | c.283A>T p.N95Y | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LY9 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAGEC2 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- MGAM | c.4051T>A p.W1351R | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MMP11 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- MMP11 | c.1309G>C p.D437H | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MSTN | c.891G>T p.W297C | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC16 | c.2929G>T p.G977W | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- MUC17 | c.11714C>G p.T3905S | Missense Mutation (SNP) | VAF 23/278 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.042); called by muse, mutect2
- MUC17 | c.12155G>A p.S4052N | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- MYO10 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 17/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO18B | c.5071T>A p.W1691R | Missense Mutation (SNP) | VAF 52/347 reads (15%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- MYO7B | c.6023G>A p.G2008E | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAV3 | c.2662A>T p.S888C | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NBN | c.369dup p.G124Wfs*37 | Frame Shift Ins (INS) | VAF 35/191 reads (18%) | called by mutect2, pindel, varscan2
- NCOR2 | c.4264G>T p.G1422C | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NELL1 | c.487C>A p.L163I | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NFXL1 | c.2621G>T p.R874I | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- NIBAN1 | c.2215C>A p.H739N | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2
- NKD2 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- NMRK2 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NOS2 | c.1352A>T p.Y451F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- NPAP1 | c.3019G>A p.V1007M | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NRXN2 | c.123C>G p.Y41* | Nonsense Mutation (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- NTRK1 | c.1418del p.G473Afs*74 | Frame Shift Del (DEL) | VAF 97/867 reads (11%) | called by mutect2, pindel, varscan2
- NWD2 | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 207/667 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NWD2 | c.4465G>T p.D1489Y | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR10P1 | c.621_624del p.F207Lfs*2 | Frame Shift Del (DEL) | VAF 107/463 reads (23%) | called by mutect2, pindel, varscan2
- OR2T2 | c.283T>A p.F95I | Missense Mutation (SNP) | VAF 100/1418 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR2T4 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 92/622 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR52H1 | c.422A>T p.K141M (on ENST00000322653; = p.K147M on NM_001005289.1) | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- OR9I1 | c.309A>T p.L103F | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAK5 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 62/545 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.459); called by mutect2, varscan2
- PAPPA | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 84/421 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PARP4 | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- PCDH11X | c.3206G>T p.G1069V | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- PCDHA7 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 50/620 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB13 | c.1667A>T p.D556V | Missense Mutation (SNP) | VAF 70/878 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PCDHGA1 | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PDE1A | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PDE3A | c.2925+1G>A p.X975_splice | Splice Site (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- PER1 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- PGBD2 | c.17G>T p.R6I | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PIKFYVE | c.4337A>G p.K1446R | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.98); called by muse, mutect2
- PIP4K2A | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PKHD1L1 | c.4351G>T p.D1451Y | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PKHD1L1 | c.4882G>A p.G1628S | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PLSCR1 | c.60del p.Y21Ifs*73 | Frame Shift Del (DEL) | VAF 26/152 reads (17%) | called by pindel, varscan2
- PLXDC2 | c.1363G>T p.G455C | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PMFBP1 | c.1138T>A p.C380S | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- PMPCA | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 24/486 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, mutect2
- POLQ | c.5527G>A p.E1843K | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- POU2F1 | c.832A>T p.S278C (on ENST00000541643 / NM_001365848.1; = p.S301C on NM_002697.4) | Missense Mutation (SNP) | VAF 49/452 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- PRAMEF6 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 69/390 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PREX2 | c.4531C>A p.L1511M | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- PSMA4 | c.401dup p.L134Ffs*8 | Frame Shift Ins (INS) | VAF 23/202 reads (11%) | called by mutect2, pindel, varscan2
- PTPN13 | c.4803G>T p.L1601F (on ENST00000411767 / NM_080683.3; = p.L1582F on NM_006264.3) | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- PXDNL | c.3171C>A p.H1057Q | Missense Mutation (SNP) | VAF 103/516 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAC2 | c.217C>G p.P73A | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- RASGRP3 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- RB1CC1 | c.4600T>A p.S1534T | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2
- RIPK3 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.216); called by muse, mutect2
- RNF213 | c.4579G>T p.G1527W | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RP1L1 | c.2290G>A p.G764R | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- RPAP1 | c.3955C>G p.Q1319E | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- RTF1 | c.1846A>C p.I616L | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- S100A8 | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- SALL4 | c.1641G>T p.E547D | Missense Mutation (SNP) | VAF 22/563 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2
- SERPINA1 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SERPINB11 | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- SETBP1 | c.1580C>A p.A527D | Missense Mutation (SNP) | VAF 49/362 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SHLD2 | c.1866A>T p.K622N | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIGLEC14 | c.422-1G>T p.X141_splice | Splice Site (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.134G>C p.R45P | Missense Mutation (SNP) | VAF 73/523 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIPA1L3 | c.3645G>T p.M1215I | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SLC17A9 | c.878G>C p.S293T | Missense Mutation (SNP) | VAF 22/435 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2
- SLC38A1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.127); called by muse, mutect2
- SLC44A3 | c.677C>G p.S226C (on ENST00000271227 / NM_001114106.3; = p.S178C on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC4A4 | c.2694G>T p.K898N (on ENST00000264485 / NM_001098484.3; = p.K854N on NM_003759.4) | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SLC7A4 | c.1835G>T p.S612I | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- SLIT3 | c.2792G>T p.C931F | Missense Mutation (SNP) | VAF 26/373 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SNX17 | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SOWAHC | c.164A>T p.H55L | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- SP140 | c.1646-2A>T p.X549_splice | Splice Site (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- SPEG | c.5956G>C p.A1986P | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.261); called by muse, mutect2
- SPEG | c.8879dup p.P2961Sfs*80 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel
- SPTBN4 | c.1690G>A p.G564R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRMS | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2
- STAT1 | c.1583-1G>A p.X528_splice | Splice Site (SNP) | VAF 42/441 reads (10%) | called by muse, mutect2, varscan2
- STK39 | c.1564-1G>T p.X522_splice | Splice Site (SNP) | VAF 27/214 reads (13%) | called by muse, mutect2, varscan2
- SVEP1 | c.1906T>A p.C636S | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SWAP70 | c.415-2A>T p.X139_splice | Splice Site (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2
- SYT9 | c.1363G>T p.V455L | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TAS2R9 | c.110A>T p.K37I | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TBC1D8 | c.2705T>A p.V902E | Missense Mutation (SNP) | VAF 12/382 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2
- TCF23 | c.223-1G>A p.X75_splice | Splice Site (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- TET3 | c.4891G>T p.A1631S | Missense Mutation (SNP) | VAF 50/469 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- TFAP2C | c.1175A>G p.H392R | Missense Mutation (SNP) | VAF 42/656 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- THAP12 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TIMD4 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 72/402 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TLX2 | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 26/548 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- TRBV7-1 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- TRIM67 | c.1970T>A p.V657E | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TRPC4 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TULP1 | c.1110G>A p.L370= | Splice Region (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- UBA6 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC80 | c.826C>A p.Q276K | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VASN | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- VPS18 | c.880T>C p.Y294H | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- WDR97 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 96/408 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- WNK2 | c.3548G>T p.R1183M | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- XIRP2 | c.5641T>A p.L1881M (on ENST00000628543; = p.L2056M on NM_152381.6) | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- YIPF7 | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 17/144 reads (12%) | called by muse, mutect2, varscan2
- ZNF10 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF148 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2
- ZNF197 | c.693G>C p.W231C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZNF292 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF385A | c.971C>T p.A324V (on ENST00000338010 / NM_001130967.3; = p.A304V on NM_015481.3) | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2
- ZNF492 | c.1293C>G p.N431K | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZNF518B | c.1478G>T p.S493I | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.28); called by muse, mutect2
- ZNF557 | c.379A>T p.K127* (on ENST00000414706 / NM_001044388.2; = p.K134* on NM_024341.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- ZNF638 | c.2002A>G p.K668E | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF729 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 51/447 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF737 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.197); called by muse, mutect2
- ZSCAN5B | c.128G>C p.W43S | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- ZZEF1 | c.8314+1G>C p.X2772_splice | Splice Site (SNP) | VAF 36/111 reads (32%) | called by muse, mutect2, varscan2
- AARS2 | c.2454G>C p.L818= | Silent (SNP) | VAF 26/470 reads (6%) | catalogued as rs1160921046; called by muse, mutect2
- ABCA3 | c.1362G>C p.G454= | Silent (SNP) | VAF 40/713 reads (6%) | called by muse, mutect2
- ABCD2 | c.1314T>C p.Y438= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as rs367708859; called by muse, mutect2, varscan2
- ADAMTS14 | c.3495C>T p.P1165= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as rs754470986; called by muse, mutect2, varscan2
- AL035461.3 | c.2614T>C p.L872= | Silent (SNP) | VAF 41/338 reads (12%) | catalogued as rs1332952757; called by muse, mutect2, varscan2
- ANK2 | c.9678C>A p.P3226= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- ATOH1 | c.675G>T p.P225= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2
- BTN2A1 | c.1224G>A p.E408= | Silent (SNP) | VAF 26/476 reads (5%) | called by muse, mutect2
- C1GALT1C1 | c.702A>T p.A234= | Silent (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- CCAR1 | c.3112T>C p.L1038= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- CLUH | c.249G>T p.T83= (on ENST00000435359; = p.T121= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/285 reads (10%) | called by muse, mutect2, varscan2
- COL20A1 | c.1212C>T p.P404= | Silent (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- COL4A4 | c.2178C>T p.D726= | Silent (SNP) | VAF 19/313 reads (6%) | called by muse, mutect2
- CPAMD8 | c.705C>T p.I235= (on ENST00000651564; = p.I188= on NM_015692.5) | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- DAB2 | c.411G>T p.V137= | Silent (SNP) | VAF 24/251 reads (10%) | called by muse, mutect2
- DENND1A | c.1464G>T p.R488= | Silent (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- DGKI | c.636C>G p.V212= | Silent (SNP) | VAF 17/230 reads (7%) | called by muse, mutect2
- DHX37 | c.2685G>A p.L895= | Silent (SNP) | VAF 17/197 reads (9%) | called by muse, mutect2
- DLGAP2 | c.330G>T p.L110= | Silent (SNP) | VAF 36/149 reads (24%) | catalogued as rs778327848; called by muse, mutect2, varscan2
- DLK2 | c.984C>A p.T328= | Silent (SNP) | VAF 30/242 reads (12%) | catalogued as rs768782924; called by muse, mutect2, varscan2
- DNAH6 | c.8562G>A p.L2854= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- EGFLAM | c.261C>T p.S87= | Silent (SNP) | VAF 44/243 reads (18%) | catalogued as rs752980145; called by muse, mutect2, varscan2
- EGR4 | c.1638C>T p.C546= (on ENST00000545030; = p.C443= on NM_001965.4) | Silent (SNP) | VAF 19/384 reads (5%) | catalogued as COSV71532455; called by muse, mutect2
- ELFN1 | c.744A>T p.S248= | Silent (SNP) | VAF 18/253 reads (7%) | called by muse, mutect2
- ELFN1 | c.2472C>A p.A824= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- F2RL2 | c.930T>C p.F310= | Silent (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- FAT2 | c.6099G>A p.Q2033= | Silent (SNP) | VAF 19/299 reads (6%) | called by muse, mutect2
- FCRL3 | c.1989C>T p.S663= | Silent (SNP) | VAF 23/241 reads (10%) | called by muse, mutect2
- FERMT2 | c.276C>T p.F92= | Silent (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- GABRG2 | c.732C>A p.S244= | Silent (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
- GDF2 | c.630C>A p.A210= | Silent (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2
- GSK3B | c.621G>A p.L207= | Silent (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- H2AC12 | c.105C>G p.L35= | Silent (SNP) | VAF 9/270 reads (3%) | called by muse, mutect2
- HAO1 | c.579T>C p.F193= | Silent (SNP) | VAF 26/362 reads (7%) | catalogued as COSV101113174, COSV66491698; called by muse, mutect2
- HCFC1 | c.219C>T p.A73= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs201762685; called by muse, mutect2, varscan2
- HGD | c.147C>T p.F49= | Silent (SNP) | VAF 30/416 reads (7%) | called by muse, mutect2
- HK2 | c.2703G>T p.A901= | Silent (SNP) | VAF 24/416 reads (6%) | catalogued as COSV51875113; called by muse, mutect2
- IL36RN | c.75G>A p.Q25= | Silent (SNP) | VAF 23/474 reads (5%) | catalogued as rs1348538791; called by muse, mutect2
- IZUMO3 | c.546G>A p.L182= (on ENST00000543880 / NM_001365008.2; = p.L176= on NM_001271706.1) | Silent (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- JPH4 | c.1698C>A p.P566= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV58114282; called by muse, mutect2, varscan2
- KRTAP11-1 | c.372G>A p.V124= | Silent (SNP) | VAF 171/456 reads (38%) | called by muse, mutect2, varscan2
- LCK | c.171G>T p.P57= | Silent (SNP) | VAF 37/162 reads (23%) | called by muse, mutect2, varscan2
- LCN6 | c.117G>A p.A39= | Silent (SNP) | VAF 20/236 reads (8%) | catalogued as rs773297141; called by muse, mutect2
- LILRB2 | c.141C>T p.L47= | Silent (SNP) | VAF 18/400 reads (5%) | catalogued as COSV58744457, COSV58747760; called by muse, mutect2
- LMBR1 | c.168C>A p.V56= | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- LMO7 | c.3678G>A p.Q1226= (on ENST00000357063; = p.Q907= on NM_005358.5) | Silent (SNP) | VAF 26/176 reads (15%) | called by muse, mutect2, varscan2
- LMOD2 | c.1305C>A p.S435= | Silent (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- LRRC4B | c.240C>A p.V80= | Silent (SNP) | VAF 55/507 reads (11%) | catalogued as COSV66753468; called by muse, mutect2, varscan2
- LY86 | c.72G>T p.G24= | Silent (SNP) | VAF 70/283 reads (25%) | called by muse, mutect2, varscan2
- MAGEC3 | c.165T>C p.H55= | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- MAGI1 | c.2040G>C p.L680= | Silent (SNP) | VAF 32/295 reads (11%) | called by muse, mutect2, varscan2
- MAK | c.39C>A p.G13= | Silent (SNP) | VAF 93/592 reads (16%) | called by muse, mutect2, varscan2
- MC3R | c.657G>A p.K219= | Silent (SNP) | VAF 148/529 reads (28%) | called by muse, mutect2, varscan2
- MROH2B | c.1584T>C p.A528= | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as rs201669549; called by muse, mutect2, varscan2
- MS4A7 | c.333G>A p.K111= | Silent (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- MUC16 | c.40203C>G p.P13401= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as COSV66689482; called by muse, mutect2
- MYADML2 | c.582C>A p.T194= | Silent (SNP) | VAF 48/345 reads (14%) | called by muse, mutect2, varscan2
- MYH8 | c.252T>A p.P84= | Silent (SNP) | VAF 43/323 reads (13%) | called by muse, mutect2, varscan2
- MYO1F | c.1002C>T p.S334= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as rs766772743; called by muse, mutect2
- MZT2B | c.36G>T p.S12= | Silent (SNP) | VAF 40/154 reads (26%) | called by muse, mutect2, varscan2
- NAALAD2 | c.1458C>T p.S486= | Silent (SNP) | VAF 15/191 reads (8%) | catalogued as rs201940664; called by muse, mutect2
- NEB | c.3456C>A p.A1152= | Silent (SNP) | VAF 31/214 reads (14%) | called by muse, mutect2, varscan2
- NLRP14 | c.2223A>T p.I741= | Silent (SNP) | VAF 24/226 reads (11%) | called by muse, mutect2, varscan2
- NMUR2 | c.234G>T p.T78= | Silent (SNP) | VAF 24/349 reads (7%) | catalogued as rs1229497090, COSV54918203; called by muse, mutect2
- NOL4 | c.837G>T p.G279= | Silent (SNP) | VAF 20/167 reads (12%) | called by muse, mutect2, varscan2
- NRK | c.117C>A p.I39= | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- OR2L5 | c.927G>T p.S309= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs528003385, COSV62364369; called by muse, varscan2
- OR2T6 | c.537T>C p.C179= | Silent (SNP) | VAF 21/210 reads (10%) | called by muse, mutect2, varscan2
- OR4C15 | c.279C>T p.G93= (on ENST00000314644; = p.G39= on NM_001001920.2) | Silent (SNP) | VAF 36/358 reads (10%) | catalogued as rs368672576; called by muse, mutect2
- PCDHA6 | c.690C>A p.V230= | Silent (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- PDE6C | c.264C>A p.A88= | Silent (SNP) | VAF 25/251 reads (10%) | called by muse, mutect2
- PIGN | c.399A>G p.T133= | Silent (SNP) | VAF 19/116 reads (16%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.48C>G p.L16= | Silent (SNP) | VAF 37/392 reads (9%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.342C>G p.V114= | Silent (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- PRKN | c.309T>A p.T103= | Silent (SNP) | VAF 60/616 reads (10%) | called by muse, mutect2
- PRRC2C | c.7461T>G p.L2487= (on ENST00000367742; = p.L2485= on NM_015172.4) | Silent (SNP) | VAF 11/336 reads (3%) | called by muse, mutect2
- PTK6 | c.150G>C p.L50= | Silent (SNP) | VAF 31/417 reads (7%) | called by muse, mutect2
- SCN9A | c.5658G>A p.R1886= (on ENST00000303354; = p.R1875= on NM_002977.3) | Silent (SNP) | VAF 13/267 reads (5%) | catalogued as COSV57612220; called by muse, mutect2
- SLC4A1 | c.682T>C p.L228= | Silent (SNP) | VAF 45/487 reads (9%) | called by muse, mutect2
- SOX17 | c.654G>A p.P218= | Silent (SNP) | VAF 31/167 reads (19%) | catalogued as rs770677973; called by muse, mutect2, varscan2
- SPICE1 | c.1818C>G p.V606= | Silent (SNP) | VAF 15/378 reads (4%) | catalogued as COSV99871469; called by muse, mutect2
- SPRY4 | c.579G>T p.L193= (on ENST00000434127 / NM_001127496.3; = p.L216= on NM_030964.4) | Silent (SNP) | VAF 62/367 reads (17%) | called by muse, mutect2, varscan2
- SPTBN2 | c.1629C>G p.L543= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as COSV59452420; called by muse, mutect2
- TECPR1 | c.105C>T p.F35= | Silent (SNP) | VAF 381/668 reads (57%) | called by muse, mutect2, varscan2
- TEX11 | c.864C>A p.L288= (on ENST00000344304; = p.L273= on NM_031276.3) | Silent (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- TFDP2 | c.1287G>A p.S429= (on ENST00000489671 / NM_001178139.2; = p.S369= on NM_006286.5) | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs768086644; called by muse, mutect2
- TPRA1 | c.1062C>G p.P354= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as rs768273416; called by muse, mutect2, varscan2
- TTC28 | c.7278G>A p.P2426= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as rs6005683; called by muse, mutect2
- TTC30A | c.837C>T p.P279= | Silent (SNP) | VAF 70/258 reads (27%) | catalogued as rs754184914; called by muse, mutect2, varscan2
- TTN | c.55365C>A p.V18455= (on ENST00000591111; = p.V11031= on NM_003319.4) | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- TTN | c.10041C>A p.I3347= (on ENST00000591111; = p.I3301= on NM_003319.4) | Silent (SNP) | VAF 29/502 reads (6%) | called by muse, mutect2
- TTN | c.9057A>G p.K3019= (on ENST00000591111; = p.K2973= on NM_003319.4) | Silent (SNP) | VAF 42/386 reads (11%) | catalogued as COSV60219332; called by muse, mutect2, varscan2
- TTN | c.4677A>T p.V1559= (on ENST00000591111; = p.V1513= on NM_003319.4) | Silent (SNP) | VAF 52/354 reads (15%) | called by muse, varscan2
- UGT2B4 | c.927G>T p.L309= | Silent (SNP) | VAF 32/354 reads (9%) | called by muse, mutect2
- UHRF1 | c.2259G>T p.R753= (on ENST00000612630 / NM_001290050.1; = p.R766= on NM_013282.4) | Silent (SNP) | VAF 50/510 reads (10%) | called by muse, mutect2
- ULBP3 | c.39C>T p.L13= | Silent (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- UNC13C | c.3885C>T p.S1295= | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- USP20 | c.2631C>T p.N877= | Silent (SNP) | VAF 10/253 reads (4%) | catalogued as rs1353655970; called by muse, mutect2
- VN1R2 | c.1116C>T p.P372= | Silent (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- WASHC5 | c.2748C>T p.V916= | Silent (SNP) | VAF 13/354 reads (4%) | called by muse, mutect2
- YTHDF1 | c.1314C>T p.F438= | Silent (SNP) | VAF 36/265 reads (14%) | called by muse, mutect2, varscan2
- ZFR2 | c.714G>T p.A238= | Silent (SNP) | VAF 21/219 reads (10%) | called by muse, mutect2, varscan2
- ZIC1 | c.1021C>A p.R341= | Silent (SNP) | VAF 28/295 reads (9%) | catalogued as rs1284303263; called by muse, mutect2
- ZMYM5 | c.1266A>G p.K422= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- ZNF628 | c.1029G>T p.P343= | Silent (SNP) | VAF 26/299 reads (9%) | called by muse, mutect2
- ZNF765 | c.360A>T p.T120= | Silent (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2
- ZNF804B | c.735C>A p.T245= | Silent (SNP) | VAF 122/254 reads (48%) | called by muse, mutect2, varscan2
- AC093791.1 | n.518A>G | RNA (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- AC107918.4 | n.4G>T | RNA (SNP) | VAF 10/109 reads (9%) | catalogued as rs1201971929; called by muse, mutect2
- AGPAT4 | c.348+4847G>A | Intron (SNP) | VAF 18/362 reads (5%) | catalogued as COSV57250544; called by muse, mutect2
- AHSG | c.-31G>A | 5'UTR (SNP) | VAF 38/344 reads (11%) | called by muse, mutect2, varscan2
- AL139327.1 | n.368G>T | RNA (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2
- ANKRD26P1 | n.1956G>A | RNA (SNP) | VAF 15/225 reads (7%) | called by muse, mutect2
- ART3 | c.847+37G>T | Intron (SNP) | VAF 28/234 reads (12%) | catalogued as COSV100587965; called by muse, mutect2, varscan2
- C14orf177 | n.435C>A | RNA (SNP) | VAF 40/287 reads (14%) | called by muse, mutect2, varscan2
- C5orf17 | n.314A>C | RNA (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- CLVS1 | c.-152+4238G>A | Intron (SNP) | VAF 13/322 reads (4%) | catalogued as rs1179095864; called by muse, mutect2
- CYLD | chr16:50806687 C>A | 3'Flank (SNP) | VAF 17/228 reads (7%) | called by muse, mutect2
- CYP2A7P1 | n.570G>A | RNA (SNP) | VAF 30/392 reads (8%) | called by muse, mutect2
- DCAF10 | c.-4G>A | 5'UTR (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- DOK6 | c.-16C>A | 5'UTR (SNP) | VAF 12/217 reads (6%) | called by muse, mutect2
- EDRF1 | c.3123+56G>C | Intron (SNP) | VAF 13/298 reads (4%) | called by muse, mutect2
- EGLN3 | c.357+13C>T | Intron (SNP) | VAF 34/347 reads (10%) | catalogued as rs1460442575, COSV51655078; called by muse, mutect2
- FAP | c.1047+25A>T | Intron (SNP) | VAF 36/123 reads (29%) | called by muse, mutect2, varscan2
- FCRL4 | c.1250-35T>C | Intron (SNP) | VAF 42/306 reads (14%) | catalogued as COSV99620330; called by muse, mutect2, varscan2
- GFAP | c.1171+88A>T | Intron (SNP) | VAF 55/359 reads (15%) | called by muse, mutect2, varscan2
- GFOD1 | c.253+16581G>T | Intron (SNP) | VAF 43/220 reads (20%) | called by muse, mutect2, varscan2
- GLRXP3 | n.108G>T | RNA (SNP) | VAF 43/410 reads (10%) | called by muse, mutect2, varscan2
- HIBCH | c.664-636A>G | Intron (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- HSD3B7 | c.532-36G>T | Intron (SNP) | VAF 54/558 reads (10%) | catalogued as COSV99288168; called by muse, mutect2
- HTR2C | c.-60C>A | 5'UTR (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- ITGAM | c.2796-41C>T | Intron (SNP) | VAF 44/412 reads (11%) | called by muse, mutect2, varscan2
- KLF6 | c.*3474G>T | 3'UTR (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- KRT71 | c.-1C>A | 5'UTR (SNP) | VAF 10/33 reads (30%) | called by muse, varscan2
- LDLRAP1 | c.89-17A>G | Intron (SNP) | VAF 20/326 reads (6%) | catalogued as rs750912798; called by muse, mutect2
- LINC00587 | n.328C>A | RNA (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- MGAM | c.4619-12122C>A | Intron (SNP) | VAF 15/472 reads (3%) | called by muse, mutect2
- MIR31 | n.21G>T | RNA (SNP) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- MSC-AS1 | n.349G>A | RNA (SNP) | VAF 21/449 reads (5%) | called by muse, mutect2
- NEB | c.8889+3594C>T | Intron (SNP) | VAF 42/460 reads (9%) | catalogued as rs751919085, COSV50883372; called by muse, mutect2
- NXF1 | c.1017-27C>T | Intron (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- OXSR1 | c.292+2495G>T | Intron (SNP) | VAF 10/294 reads (3%) | called by muse, mutect2
- PFDN4 | chr20:54224251 A>T | 3'Flank (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- PKD1 | c.10050+22G>T | Intron (SNP) | VAF 138/674 reads (20%) | called by mutect2, varscan2
- PKD1L2 | chr16:81139644 A>T | 5'Flank (SNP) | VAF 43/312 reads (14%) | called by muse, mutect2, varscan2
- PLCG2 | c.*55G>T | 3'UTR (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- PLD5 | c.189+74734G>T | Intron (SNP) | VAF 29/228 reads (13%) | called by muse, mutect2, varscan2
- PRCD | chr17:76543830 G>A | 3'Flank (SNP) | VAF 17/312 reads (5%) | called by muse, mutect2
- PTMA | c.46-732A>T | Intron (SNP) | VAF 27/188 reads (14%) | catalogued as rs1249794190; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2290-33G>T | Intron (SNP) | VAF 30/286 reads (10%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.2290-32C>T | Intron (SNP) | VAF 30/289 reads (10%) | catalogued as rs1423473028; called by muse, mutect2, varscan2
- RASGEF1C | c.*5G>T | 3'UTR (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- SIPA1L3 | c.2030-15G>T | Intron (SNP) | VAF 46/393 reads (12%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1747G>C | Intron (SNP) | VAF 26/258 reads (10%) | catalogued as COSV100678897; called by muse, mutect2, varscan2
